Somatic mutation profile of tumor specimen TCGA-2G-AAFL-01A (aliquot TCGA-2G-AAFL-01A-21D-A42Y-10) from TCGA case TCGA-2G-AAFL, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 35.3 years (12,898 days).
Specimen TCGA-2G-AAFL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8af59e45-50e3-4695-baf0-55238b46b100.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFL-10A (Blood Derived Normal), aliquot TCGA-2G-AAFL-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a13801e5-57b5-435d-ab81-928995935f42

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Nonsense Mutation 1, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM170A | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as rs567555202, COSV58926948; called by muse, mutect2, varscan2
- PHF20L1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765178242; called by muse, mutect2, varscan2
- SLC39A10 | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs774374730; called by muse, mutect2
- WDR25 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.018); catalogued as rs546879041; called by muse, mutect2, varscan2
- ARNT | c.2209C>G p.R737G | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASD1 | c.2114A>T p.K705I | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- COL11A1 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- KRT23 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- PPP1R3A | c.3139G>A p.D1047N | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- TULP3 | c.609A>C p.R203S | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CHM | c.411C>T p.A137= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV63300034; called by muse, mutect2, varscan2
- ITSN1 | c.1176G>A p.E392= | Silent (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2, varscan2
- MAP3K4 | c.4575G>A p.A1525= | Silent (SNP) | VAF 7/127 reads (6%) | catalogued as rs969693064, COSV62332440; called by muse, mutect2
- MUC5B | c.13479C>T p.S4493= | Silent (SNP) | VAF 40/327 reads (12%) | called by muse, mutect2, varscan2
- OLFML3 | c.921C>T p.D307= | Silent (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- SUPT16H | c.1719T>C p.Y573= | Silent (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- CCNE2 | c.112-20T>C | Intron (SNP) | VAF 20/198 reads (10%) | catalogued as rs1316129416; called by muse, mutect2, varscan2
- NCF1C | n.977_998del | RNA (DEL) | VAF 23/180 reads (13%) | called by mutect2, pindel, varscan2
- TRIM66 | c.-23G>A | 5'UTR (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
